TCGA case TCGA-86-8074 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/482eb2a7-6fed-4e4c-b1b6-14d6d869f855

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.6 years (22,862 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: No.

Follow-up (2 entries)
- Days to follow up: 24 days; Disease response: Tumor Free.
- Karnofsky performance status: 80; ECOG performance status: 2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40; Tobacco smoking onset year: 1970.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-86-8074-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.3; Intermediate dimension: 1.3; Shortest dimension: 0.3.
  Slide TCGA-86-8074-01A-01-TS1: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-86-8074-01A-01-BS1: Section location: Bottom; Percent tumor cells: 96; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-86-8074-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-86-8074-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: No.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 24 days; disease-specific survival: no event (censored), 24 days; progression-free interval: no event (censored), 24 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-86-8074-01A-11D-2237-01): tumor purity 0.51, ploidy 3.81, whole-genome doublings 2.
